Somatic mutation profile of tumor specimen TCGA-AG-3598-01A (aliquot TCGA-AG-3598-01A-01D-1989-10) from TCGA case TCGA-AG-3598, project TCGA-READ (Rectum Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectosigmoid junction; AJCC pathologic stage: Stage IIA; Age at diagnosis: 69.3 years (25,324 days).
Specimen TCGA-AG-3598-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9ea3bbc4-c525-4182-ba55-b3fcc2415045.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AG-3598-10A (Blood Derived Normal), aliquot TCGA-AG-3598-10A-01D-1989-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5f164d68-c28b-4ae4-9207-3e8f92c526fb

The open-access MAF lists 23 somatic variants for this specimen: 21 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 18, Silent 2, Frame Shift Ins 1, Nonsense Mutation 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GAL3ST2 | c.197C>T p.T66M | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs372108744, CM1412990; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- AQR | c.1125C>A p.N375K | Missense Mutation (SNP) | VAF 97/264 reads (37%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV99333592; called by muse, mutect2, varscan2
- CIC | c.3214G>A p.V1072M | Missense Mutation (SNP) | VAF 18/32 reads (56%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.288); catalogued as rs781265178, COSV50557087; called by muse, mutect2, varscan2
- COL24A1 | c.3416T>A p.I1139N | Missense Mutation (SNP) | VAF 24/360 reads (7%) | SIFT tolerated (0.61); PolyPhen benign (0.21); catalogued as COSV100993098; called by muse, mutect2
- CRACD | c.2374G>T p.A792S | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.87); catalogued as COSV99948923; called by muse, mutect2, varscan2
- CRTAC1 | c.1894G>A p.A632T | Missense Mutation (SNP) | VAF 29/81 reads (36%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs1306143159, COSV53997072; called by muse, mutect2, varscan2
- FER1L6 | c.4018G>A p.G1340R | Missense Mutation (SNP) | VAF 126/442 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.352); catalogued as rs759909451, COSV67551017; called by muse, mutect2, varscan2
- FSIP2 | c.17514G>C p.E5838D | Missense Mutation (SNP) | VAF 12/109 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100553905, COSV100554592, COSV100556893; called by muse, mutect2
- HELZ2 | c.4783C>T p.R1595W (on ENST00000467148 / NM_001037335.2; = p.R1026W on NM_033405.3) | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as rs375889877; called by muse, mutect2, varscan2
- MYO5C | c.1843C>G p.P615A | Missense Mutation (SNP) | VAF 36/375 reads (10%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as COSV99954414; called by muse, mutect2
- PCDH8 | c.17G>A p.R6H | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); catalogued as COSV100131384; called by muse, mutect2, varscan2
- PRTG | c.1834A>G p.K612E | Missense Mutation (SNP) | VAF 43/121 reads (36%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.994); catalogued as COSV101221335; called by muse, mutect2, varscan2
- PSMB8 | c.73G>T p.G25W | Missense Mutation (SNP) | VAF 62/126 reads (49%) | SIFT deleterious (0.04); PolyPhen benign (0.01); catalogued as COSV100841146; called by muse, mutect2, varscan2
- SIAH3 | c.151C>T p.R51C | Missense Mutation (SNP) | VAF 46/148 reads (31%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); catalogued as rs200127410, COSV68551773; called by muse, mutect2, varscan2
- SLC5A10 | c.280G>T p.E94* | Nonsense Mutation (SNP) | VAF 12/27 reads (44%) | catalogued as COSV100524948; called by mutect2, varscan2
- SPINK13 | c.28_29insG p.F10Cfs*19 | Frame Shift Ins (INS) | VAF 180/686 reads (26%) | catalogued as COSV101268288; called by mutect2, pindel, varscan2
- ST6GALNAC2 | c.123C>A p.A41= | Splice Region (SNP) | VAF 5/16 reads (31%) | catalogued as COSV99833328; called by muse, mutect2
- TOR4A | c.382G>A p.A128T | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.071); catalogued as COSV62626722; called by muse, mutect2, varscan2
- ZNF703 | c.1723G>A p.A575T | Missense Mutation (SNP) | VAF 23/73 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.978); catalogued as rs775245530, COSV100521695; called by muse, mutect2, varscan2
- ZNRF4 | c.1048G>A p.V350M | Missense Mutation (SNP) | VAF 59/166 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0.196); catalogued as rs540854812, COSV55773698; called by muse, mutect2, varscan2
- KLF14 | c.697G>A p.D233N | Missense Mutation (SNP) | VAF 10/106 reads (9%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.66); called by muse, mutect2
- CSPG4 | c.1494C>T p.D498= | Silent (SNP) | VAF 5/11 reads (45%) | catalogued as rs762962963, COSV57896661, COSV57900665; called by muse, mutect2, varscan2
- SHD | c.144C>T p.D48= | Silent (SNP) | VAF 25/68 reads (37%) | catalogued as rs1444108887, COSV101619030; called by muse, mutect2, varscan2
